Somatic mutation profile of tumor specimen 0DTB8S from CCDI case PBCJGG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,221 days).
Specimen 0DTB8S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f253701a-ba81-4958-bfb1-4c26f8e8ee92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8I (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79041967-b4e9-4eba-9a0e-75a331de03d2

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 5, 3'UTR 2, Silent 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A5 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 53/542 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs976274616, COSV55208289; called by muse, mutect2
- KBTBD4 | c.884_886dup p.P295dup | In Frame Ins (INS) | VAF 141/358 reads (39%) | catalogued as COSV58596732, COSV58597734, COSV58597899; called by mutect2, pindel, varscan2
- PANX2 | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs1442658555; called by muse, mutect2, varscan2
- RGS12 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 41/606 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148112019; called by muse, mutect2
- PDK2 | c.556A>G p.K186E | Missense Mutation (SNP) | VAF 46/608 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2
- TAS2R60 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 184/479 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ZBTB7A | c.45C>G p.D15E | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLITRK5 | c.81G>A p.A27= | Silent (SNP) | VAF 42/712 reads (6%) | catalogued as rs773771804, COSV100280789, COSV61520859; called by muse, mutect2
- TMEM200C | c.963C>T p.A321= | Silent (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- CROCC2 | c.3094-11del | Intron (DEL) | VAF 62/275 reads (23%) | called by mutect2, pindel, varscan2
- DDB2 | c.1024-25C>T | Intron (SNP) | VAF 74/344 reads (22%) | called by muse, mutect2, varscan2
- H4C5 | c.*39A>G | 3'UTR (SNP) | VAF 86/332 reads (26%) | called by muse, mutect2, varscan2
- KIAA0895 | c.868-1118C>T | Intron (SNP) | VAF 91/253 reads (36%) | called by muse, mutect2, varscan2
- OVCH1 | c.1930-32C>T | Intron (SNP) | VAF 27/140 reads (19%) | catalogued as rs780089822; called by muse, mutect2, varscan2
- RCE1 | c.692-29G>A | Intron (SNP) | VAF 14/127 reads (11%) | called by muse, mutect2, varscan2
- THEM5 | c.*74C>T | 3'UTR (SNP) | VAF 34/156 reads (22%) | called by muse, varscan2
